Gene-level copy-number profile of tumor specimen ALCH-B1OY-TTP1-A from ALCHEMIST case ALCH-B1OY, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 55.0 years (20,079 days).
Specimen ALCH-B1OY-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0d6b1494-08fe-46f3-a2be-ecb6b3d376c8.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1OY-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,859 have no estimate.
https://portal.gdc.cancer.gov/files/617a07a3-1e36-4c15-86f0-954b15d8bac2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 15; copy number 1: 2,876; copy number 2: 55,471; copy number 3: 388; copy number 4: 6; copy number 5: 4; copy number 6: 1; copy number 9: 1; copy number 10: 2.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:49,689,538–49,723,973, 3 genes: RNF123, AMIGO3, GMPPB.
- chr4:673,580–689,271, 2 genes (within-gene range 0–2): MYL5, SLC49A3.
- chr16:32,475,051–32,478,250, 1 gene: ABCD1P3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 8 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr21:43,053,191–43,107,570, 2 genes, copy number 6–9: CBS, U2AF1.
- chr22:18,636,445–18,653,617, 2 genes, copy number 10: CA15P2, PPP1R26P2.
- chr22:18,846,811–18,894,407, 4 genes, copy number 5: AC008132.1, BCRP7, FAM230F, AC008103.1.

Autosomal genes at a single copy (total copy number 1): 239. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
